Somatic mutation profile of tumor specimen TCGA-F4-6856-01A (aliquot TCGA-F4-6856-01A-11D-1924-10) from TCGA case TCGA-F4-6856, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 45.2 years (16,519 days).
Specimen TCGA-F4-6856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 528a45db-6c24-427b-9f91-fb93f9672b90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6856-10A (Blood Derived Normal), aliquot TCGA-F4-6856-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7540a783-59f1-4c6c-920f-3de0dab128a4

The open-access MAF lists 1,202 somatic variants for this specimen: 904 protein-altering or splice-affecting, 270 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 609, Silent 270, Frame Shift Del 183, Frame Shift Ins 50, Nonsense Mutation 30, In Frame Del 13, Intron 13, Splice Site 11, Splice Region 7, 3'UTR 6, RNA 6, 3'Flank 2.

Variants (750 of 1,202; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1350dup p.L451Afs*27 | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | catalogued as rs746723399; ClinVar: pathogenic; called by mutect2, varscan2
- ASPM | c.7857dup p.Q2620Tfs*17 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs797045316; ClinVar: pathogenic; called by mutect2, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 73/118 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 26/102 reads (25%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 50/251 reads (20%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KAT6B | c.5389C>T p.R1797* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as rs199470484, CM119247, COSV54751807; ClinVar: pathogenic / not provided; called by mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MNX1 | c.53dup p.R19Tfs*37 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs1554594329; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.17_18del p.K6Rfs*4 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | catalogued as rs121913290; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMPRSS6 | c.1786del p.A596Pfs*8 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | catalogued as rs767094129, CD082210; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440del p.A2481Pfs*7 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs768554605, COSV55290967; called by muse, mutect2, varscan2
- AADACL3 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.073); catalogued as rs78526061; called by muse, mutect2, varscan2
- AASS | c.2076del p.P693Qfs*3 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs768943469; called by mutect2, pindel, varscan2
- ABCA4 | c.5989A>G p.T1997A | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as COSV64675982; called by muse, mutect2, varscan2
- ABCC1 | c.4573G>A p.A1525T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60690887; called by muse, mutect2, varscan2
- ABHD15 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs776728486, COSV104407109, COSV56196235; called by muse, mutect2, varscan2
- ACIN1 | c.3964A>G p.K1322E | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52979394; called by muse, varscan2
- ACO1 | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59377051, COSV59382821; called by muse, mutect2, varscan2
- ACOXL | c.1343G>A p.R448Q (on ENST00000389811 / NM_001371254.1; = p.R418Q on NM_001142807.4) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs148543890; called by muse, varscan2
- ACTRT3 | c.786T>A p.C262* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV57754922; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 44/86 reads (51%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAMTS4 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs900438043, COSV63488329; called by muse, mutect2, varscan2
- ADAMTSL1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs201308391, COSV52820844; called by muse, varscan2
- ADCY8 | c.3305G>A p.G1102D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53919126; called by muse, mutect2, varscan2
- ADGRG6 | c.3243G>A p.W1081* | Nonsense Mutation (SNP) | VAF 53/239 reads (22%) | catalogued as COSV51593581; called by muse, mutect2, varscan2
- ADGRV1 | c.6677A>G p.E2226G | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as COSV67991435; called by muse, mutect2, varscan2
- ADIPOR2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs750803822, COSV63945473; called by muse, mutect2
- ADRA2C | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57467127; called by muse, mutect2, varscan2
- ADRB3 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61462374; called by muse, mutect2, varscan2
- ADSL | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV53409130; called by muse, mutect2, varscan2
- AGRN | c.3003dup p.G1002Rfs*58 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | catalogued as rs763573703; called by mutect2, varscan2
- AHNAK | c.2372A>G p.D791G | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); catalogued as COSV57223493; called by muse, mutect2, varscan2
- AK1 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.518); catalogued as rs201971818, COSV56345454; called by muse, mutect2
- AK9 | c.2845G>T p.G949* | Nonsense Mutation (SNP) | VAF 13/136 reads (10%) | catalogued as COSV58146916; called by muse, mutect2
- AKAP11 | c.2743A>C p.T915P | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV50299283; called by muse, mutect2, varscan2
- AKR1B1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs770279911, COSV53648323; called by muse, mutect2, varscan2
- AKT1S1 | c.275G>T p.S92I (on ENST00000344175 / NM_001098633.4; = p.S112I on NM_032375.5) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV99680944; called by muse, mutect2, varscan2
- ALDH18A1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1305993720, COSV64662642; called by muse, mutect2, varscan2
- ALS2 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV51890469; called by muse, mutect2, varscan2
- ALS2 | c.579A>C p.Q193H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51890483; called by muse, mutect2, varscan2
- ANGPT4 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs368267857; called by muse, mutect2, varscan2
- ANKDD1A | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777675671, COSV60353929; called by muse, mutect2, varscan2
- ANKRD12 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs568044210, COSV50837292; called by muse, mutect2, varscan2
- ANKRD17 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58225095; called by muse, mutect2, varscan2
- AP000311.1 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV51708932; called by muse, mutect2, varscan2
- AP2A2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV59960835; called by muse, mutect2, varscan2
- APBA2 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68793815; called by muse, mutect2, varscan2
- APBB1 | c.1252dup p.E418Gfs*12 | Frame Shift Ins (INS) | VAF 30/98 reads (31%) | catalogued as rs1378386109; called by mutect2, pindel, varscan2
- APBB3 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.996); catalogued as COSV60053558; called by muse, mutect2, varscan2
- APLP1 | c.1933C>T p.R645C (on ENST00000221891 / NM_001024807.3; = p.R644C on NM_005166.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55705611; called by muse, mutect2, varscan2
- APLP2 | c.1890G>T p.E630D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV53839065, COSV53842874; called by muse, mutect2, varscan2
- APOA4 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs561416907, COSV63360975; called by muse, varscan2
- APPL1 | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV55702476; called by muse, varscan2
- ARHGAP27 | c.2283G>T p.W761C (on ENST00000428638 / NM_001282290.1; = p.W420C on NM_199282.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65358297; called by muse, mutect2, varscan2
- ARHGAP44 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs77850388, COSV52390882; called by mutect2, varscan2
- ARHGEF26 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs767447466, COSV62850398; called by muse, mutect2
- ARID4B | c.666-3_666-2del p.X222_splice | Splice Site (DEL) | VAF 40/125 reads (32%) | catalogued as rs775769845; called by pindel, varscan2
- ARID5B | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.996); catalogued as COSV54426554; called by muse, mutect2, varscan2
- ARMC9 | c.1523C>A p.S508* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100589641, COSV63022614; called by mutect2, varscan2
- ARSF | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs139923989, COSV63840485; called by muse, mutect2, varscan2
- ASAP1 | c.2509A>G p.T837A | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100727871; called by muse, mutect2, varscan2
- ASB8 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs747598837, COSV58350916; called by muse, mutect2, varscan2
- ASH1L | c.7619G>A p.R2540Q (on ENST00000368346 / NM_001366177.2; = p.R2535Q on NM_018489.3) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs776090224, COSV64209384; called by mutect2, varscan2
- ASIC2 | c.636dup p.T213Dfs*15 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs1266252263; called by mutect2, varscan2
- ASS1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61690227; called by muse, mutect2, varscan2
- ATG16L2 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs553100451, COSV58362499; called by muse, mutect2, varscan2
- ATG4D | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV57265395; called by muse, mutect2, varscan2
- ATL3 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs759377612, COSV60297570; called by muse, mutect2, varscan2
- ATP2B2 | c.1269del p.V424Sfs*14 (on ENST00000352432; = p.V390Sfs*14 on NM_001683.5) | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as COSV59507522; called by mutect2, pindel, varscan2
- ATP2B2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1057261655, COSV59490646, COSV59499981; called by muse, mutect2, varscan2
- ATP2B4 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs1436632338, COSV58181687; called by muse, mutect2, varscan2
- ATP6V1D | c.309T>C p.G103= | Splice Region (SNP) | VAF 54/169 reads (32%) | catalogued as COSV53600237; called by muse, mutect2, varscan2
- ATP9A | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV58769895; called by muse, mutect2, varscan2
- ATXN1 | c.858del p.S287Pfs*38 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs774055637, COSV104392095; called by mutect2, pindel, varscan2
- B3GNT4 | c.449del p.G150Afs*4 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as COSV57336768; called by mutect2, pindel, varscan2
- B4GALNT4 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV100327432, COSV57324064; called by muse, mutect2
- BCAM | c.1727del p.G576Afs*20 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | catalogued as rs1568574840; called by mutect2, pindel, varscan2
- BCL6 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51654401; called by muse, mutect2, varscan2
- BCL6B | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs573289461, COSV53428918; called by mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs756382429; called by mutect2, varscan2
- BCO2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752219938, COSV63063308; called by muse, mutect2, varscan2
- BCORL1 | c.4457C>T p.A1486V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54392649; called by muse, mutect2, varscan2
- BDNF | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1048221, COSV59237026; called by muse, mutect2, varscan2
- BHLHE40 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV56576131; called by muse, mutect2, varscan2
- BICD1 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as rs1363511738, COSV55676223; called by muse, mutect2, varscan2
- BICD2 | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV63550245; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs755506199; called by mutect2, varscan2
- BPIFB2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV50068368; called by muse, mutect2, varscan2
- BTBD7 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs143569452; called by muse, mutect2
- BYSL | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57829169; called by muse, mutect2, varscan2
- C1S | c.842dup p.W283Lfs*14 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as rs781818365; called by mutect2, varscan2
- C1orf122 | c.268del p.Q90Sfs*42 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs747134922; called by mutect2, pindel, varscan2
- C3orf20 | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV53787713; called by muse, mutect2, varscan2
- C6orf118 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs149970829; called by muse, mutect2, varscan2
- C9 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV54679467; called by muse, mutect2, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | catalogued as COSV61714509; called by mutect2, varscan2
- CALHM5 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV62068256; called by muse, mutect2, varscan2
- CAPN10 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs149240512, COSV54376924; called by muse, mutect2, varscan2
- CAPN13 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs374775173, COSV54433263; called by muse, mutect2, varscan2
- CAPNS1 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53085123; called by muse, mutect2
- CAPZB | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1266726751, COSV51644589; called by muse, mutect2, varscan2
- CARD14 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs747495913, COSV60121629; called by muse, mutect2, varscan2
- CARD14 | c.1437del p.S480Afs*49 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs780143594; called by mutect2, pindel, varscan2
- CARMIL1 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); catalogued as COSV61515483, COSV61521496; called by muse, mutect2
- CASZ1 | c.3917G>A p.G1306D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV59739151; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CCAR2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51515309; called by muse, mutect2
- CCDC180 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs750911599, COSV63829410; called by muse, mutect2, varscan2
- CCDC180 | c.4117G>A p.A1373T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs147885690; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 72/228 reads (32%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC82 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768645326, COSV53595144; called by mutect2, varscan2
- CCNB3 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs781979096, COSV52077460, COSV52079373; called by muse, mutect2, varscan2
- CCNJ | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as COSV56443903; called by mutect2, varscan2
- CCT6A | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1198748570, COSV51907061; called by muse, mutect2, varscan2
- CD19 | c.306del p.S103Lfs*27 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as COSV100218241; called by mutect2, pindel
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | catalogued as rs760923345; called by mutect2, varscan2
- CDC14A | c.375dup p.Y126Lfs*35 | Frame Shift Ins (INS) | VAF 36/140 reads (26%) | catalogued as rs773911500; called by mutect2, varscan2
- CDC42BPA | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs780626034, COSV62016746; called by muse, mutect2, varscan2
- CDH11 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs377191094, COSV51761172; called by muse, mutect2, varscan2
- CDK16 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs750593584, COSV52093277; called by muse, mutect2, varscan2
- CELSR1 | c.4451G>A p.R1484H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53095959; called by muse, mutect2, varscan2
- CEP104 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV65518693; called by muse, mutect2, varscan2
- CFAP47 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1164903778, COSV57971771, COSV57976184; called by muse, mutect2, varscan2
- CFAP61 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99846678; called by muse, mutect2, varscan2
- CFAP61 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1337451135, COSV55640141; called by muse, mutect2, varscan2
- CGN | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs889237608, COSV99642847; called by muse, varscan2
- CGNL1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV55572318; called by muse, mutect2, varscan2
- CHD1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV52343096; called by muse, mutect2, varscan2
- CHD2 | c.5008T>C p.Y1670H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs775504391, COSV67712513; called by muse, mutect2, varscan2
- CHMP7 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); catalogued as COSV57533509; called by muse, mutect2, varscan2
- CHPF | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774421410, COSV60535036; called by muse, mutect2, varscan2
- CHRNA3 | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV58776436; called by muse, mutect2, varscan2
- CHST2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58886476; called by muse, mutect2, varscan2
- CHST3 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64151482; called by muse, mutect2, varscan2
- CIAO3 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs545716248, COSV52403589; called by mutect2, varscan2
- CIB3 | c.355_357del p.N119del | In Frame Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs760673592; called by pindel, varscan2
- CIITA | c.629-1G>A p.X210_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV60860230; called by muse, mutect2, varscan2
- CLCN4 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750086703, COSV66465446; called by muse, mutect2, varscan2
- CLCN7 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV51972454; called by muse, mutect2, varscan2
- CLCNKA | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as COSV58893141; called by muse, mutect2, varscan2
- CLDN10 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs753799088, COSV54825537; called by muse, varscan2
- CLEC2L | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs768735887, COSV70691414; called by muse, mutect2, varscan2
- CLIP2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151111065; ClinVar: uncertain significance; called by muse, mutect2
- CLIP2 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV56283327; called by muse, mutect2, varscan2
- CLIP3 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV62113163; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CNGB3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs146488853, COSV99082035; called by muse, mutect2, varscan2
- CNTN2 | c.2662G>A p.V888M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs775579054, COSV59351864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL13A1 | c.603G>T p.P201= (on ENST00000398978 / NM_001130103.2; = p.P163= on NM_080798.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 19/134 reads (14%) | catalogued as COSV100637276, COSV62572697; called by muse, mutect2, varscan2
- COL20A1 | c.2742G>T p.E914D | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58923382; called by muse, mutect2, varscan2
- COL5A1 | c.3224G>A p.G1075D | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65672764; called by muse, mutect2, varscan2
- COL5A2 | c.1566T>G p.G522= | Splice Region (SNP) | VAF 29/109 reads (27%) | catalogued as COSV100880825; called by muse, mutect2, varscan2
- COL6A6 | c.2746A>G p.I916V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV62032382; called by muse, mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- COLGALT2 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs780516386, COSV62300903; called by muse, mutect2, varscan2
- CPEB2 | c.2557-1G>T p.X853_splice | Splice Site (SNP) | VAF 33/118 reads (28%) | catalogued as COSV52593815; called by muse, mutect2, varscan2
- CPED1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as COSV60008400; called by muse, mutect2, varscan2
- CPZ | c.301G>T p.G101C (on ENST00000360986 / NM_001014447.3; = p.G90C on NM_003652.3) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59923507; called by muse, mutect2, varscan2
- CRISPLD1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51551479; called by muse, mutect2, varscan2
- CRTAP | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs145644749; called by muse, mutect2, varscan2
- CRYL1 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV53420260; called by muse, mutect2, varscan2
- CSMD3 | c.5567G>A p.G1856E (on ENST00000297405 / NM_001363185.1; = p.G1752E on NM_052900.3) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52185258, COSV52246896, COSV52260607; called by muse, mutect2, varscan2
- CSMD3 | c.1708A>T p.S570C (on ENST00000297405 / NM_001363185.1; = p.S466C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52260629; called by muse, mutect2, varscan2
- CTNNB1 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV62715187; called by muse, mutect2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs761516328; called by mutect2, pindel
- CTNND1 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs758420026, COSV62383742; called by muse, mutect2, varscan2
- CTSH | c.875dup p.N292Kfs*119 | Frame Shift Ins (INS) | VAF 36/103 reads (35%) | catalogued as rs1470013664; called by mutect2, varscan2
- CTSZ | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs201081854; called by muse, mutect2, varscan2
- CTU2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs766039051, COSV56332978, COSV56341001; called by muse, mutect2, varscan2
- CYP2C18 | c.1360C>A p.Q454K | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53673964; called by muse, mutect2, varscan2
- DAAM2 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371806282, COSV51317446; called by mutect2, varscan2
- DAPK1 | c.3050G>A p.S1017N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV100802751; called by muse, mutect2
- DBNL | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV68881818; called by muse, mutect2, varscan2
- DCAF4L2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs780981376, COSV100151233, COSV60476833; called by muse, mutect2, varscan2
- DCAF7 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60408303; called by muse, mutect2, varscan2
- DCTN1 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs748845608, COSV62621084; called by muse, mutect2, varscan2
- DDR1 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.32); catalogued as rs145280414; called by muse, mutect2, varscan2
- DDX18 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 115/367 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as COSV54308190; called by muse, mutect2, varscan2
- DENND1C | c.90del p.I31Sfs*81 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs757060526; called by mutect2, pindel
- DENND6A | c.1074dup p.A359Cfs*2 | Frame Shift Ins (INS) | VAF 18/75 reads (24%) | catalogued as rs34959359; called by mutect2, varscan2
- DERL1 | c.296_299del p.L99Sfs*11 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs768881035; called by pindel, varscan2
- DHX8 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs146727331; called by muse, mutect2, varscan2
- DHX9 | c.1847A>G p.Y616C | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62360526; called by muse, mutect2, varscan2
- DIP2C | c.503T>C p.I168T | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55148264, COSV55170855; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs762874947; called by mutect2, varscan2
- DMPK | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs199731275, COSV52180656; called by mutect2, varscan2
- DNAH11 | c.10967G>A p.R3656H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs765797284, COSV60958091; called by muse, mutect2, varscan2
- DNAH11 | c.11743G>C p.D3915H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV60969959, COSV60977315; called by muse, mutect2, varscan2
- DNAH2 | c.6265G>A p.G2089S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs1160862065, COSV66723402; called by muse, mutect2, varscan2
- DNAH3 | c.6085T>C p.Y2029H | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.825); catalogued as COSV99770696; called by muse, mutect2, varscan2
- DNAH8 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs199804814, COSV100542729; called by muse, mutect2, varscan2
- DOCK5 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV52407107; called by muse, mutect2, varscan2
- DOT1L | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs772273572, COSV67112029; called by muse, mutect2, varscan2
- DPP10 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs764715614, COSV59662512; called by muse, mutect2, varscan2
- DSPP | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 53/180 reads (29%) | catalogued as COSV56813799; called by muse, mutect2, varscan2
- DZANK1 | c.1376G>T p.R459M (on ENST00000262547 / NM_001099407.1; = p.R266M on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV52754816; called by muse, mutect2, varscan2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- EBF3 | c.1352C>T p.T451M (on ENST00000355311 / NM_001375392.1; = p.T442M on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs771970438, COSV62474563; called by muse, mutect2, varscan2
- EEF1D | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV57821683; called by muse, mutect2, varscan2
- EFHC2 | c.1314dup p.A439Cfs*10 | Frame Shift Ins (INS) | VAF 32/68 reads (47%) | catalogued as rs752671785; called by mutect2, varscan2
- EGR2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.396); catalogued as rs115534601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGR3 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100416287; called by muse, mutect2, varscan2
- EIF2AK3 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs761048614, COSV57550417; called by muse, mutect2, varscan2
- EIF4EBP2 | c.120dup p.T41Dfs*15 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | catalogued as rs751644163; called by mutect2, pindel, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs1290746509; called by mutect2, pindel, varscan2
- ENTHD1 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57323093; called by muse, mutect2, varscan2
- ENTPD3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs766379734, COSV57193743; called by muse, mutect2, varscan2
- ENTPD4 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs202242195, COSV100652795; called by muse, mutect2, varscan2
- EPHB2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs755610456, COSV65864638; called by muse, mutect2, varscan2
- EPX | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748790405, COSV56598291; called by muse, mutect2, varscan2
- ERBIN | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52322958; called by muse, mutect2, varscan2
- ERC2 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755363012, COSV55612508; called by muse, mutect2, varscan2
- ERCC4 | c.2608G>A p.V870I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.131); catalogued as rs562305007, COSV61313240; ClinVar: not provided; called by muse, mutect2, varscan2
- ESF1 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99176537; called by muse, mutect2, varscan2
- ESF1 | c.617C>G p.T206R | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.08); catalogued as COSV99176540; called by muse, mutect2
- EXOC5 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV61771774; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM153A | c.330C>T p.N110= | Splice Region (SNP) | VAF 36/476 reads (8%) | catalogued as rs142185775; called by muse, mutect2
- FAM171B | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as rs145287585; called by muse, mutect2, varscan2
- FAM50A | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs141522232, COSV50131935; called by muse, mutect2, varscan2
- FAR1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV100701662; called by muse, mutect2, varscan2
- FASN | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV60758429; called by muse, mutect2, varscan2
- FAT3 | c.10043C>T p.A3348V | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs376234071, COSV53112247; called by muse, mutect2, varscan2
- FBN1 | c.4290A>C p.E1430D | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV57325348; called by muse, mutect2, varscan2
- FBN1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.4); catalogued as rs141551765, CM145705; ClinVar: uncertain significance; called by muse, varscan2
- FBXL6 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs1554852949, COSV57352849; called by muse, mutect2, varscan2
- FBXO11 | c.2000A>G p.Q667R (on ENST00000403359 / NM_001190274.2; = p.Q583R on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV57021098, COSV57021955, COSV57023890; called by muse, mutect2, varscan2
- FBXO31 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1174331035, COSV61150241; called by muse, mutect2, varscan2
- FBXW5 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV56403697; called by muse, mutect2, varscan2
- FCHSD2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs1390308788, COSV60812906; called by muse, mutect2, varscan2
- FCRL1 | c.850del p.A284Pfs*7 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | catalogued as COSV63824536, COSV63826643; called by mutect2, pindel, varscan2
- FEZ1 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV99631197; called by muse, mutect2, varscan2
- FGF11 | c.411G>A p.P137= | Splice Region (SNP) | VAF 29/78 reads (37%) | catalogued as rs756968452, COSV53440665; called by muse, mutect2, varscan2
- FGL1 | c.753_755del p.E251del | In Frame Del (DEL) | VAF 30/72 reads (42%) | catalogued as rs545830500; called by pindel, varscan2
- FKBP5 | c.91_92del p.R31Gfs*13 | Frame Shift Del (DEL) | VAF 29/159 reads (18%) | catalogued as rs781180464, COSV61883042; called by mutect2, pindel, varscan2
- FLNC | c.2983G>A p.G995S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs752053093, COSV57955432; called by muse, mutect2, varscan2
- FMN2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100147150; called by muse, mutect2
- FMNL3 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53303710, COSV53305554; called by muse, mutect2, varscan2
- FNDC1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as rs267600879, COSV51944087; called by muse, mutect2, varscan2
- FNIP1 | c.2196dup p.P733Tfs*4 | Frame Shift Ins (INS) | VAF 44/162 reads (27%) | catalogued as rs1561647070; called by mutect2, varscan2
- FOXD4L5 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 87/457 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.022); catalogued as rs201454049, COSV66241043; called by muse, mutect2, varscan2
- FOXO3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs1245687963, COSV100670216; called by muse, mutect2
- FOXP2 | c.2003+2T>C p.X668_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV63490833; called by muse, mutect2, varscan2
- FRAS1 | c.4187A>G p.H1396R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV53631514; called by muse, mutect2, varscan2
- FRMD8 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs758310158, COSV58212206; called by muse, mutect2, varscan2
- FRYL | c.1830G>A p.W610* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV51955599; called by muse, mutect2, varscan2
- FUBP3 | c.1278+1G>A p.X426_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV60515724; called by muse, mutect2, varscan2
- FZD5 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99776527; called by muse, mutect2, varscan2
- GARRE1 | c.2525G>T p.G842V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55102125; called by muse, mutect2, varscan2
- GCN1 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs981778548, COSV56107837; called by muse, mutect2, varscan2
- GCNT4 | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 36/88 reads (41%) | catalogued as COSV59281390; called by muse, mutect2, varscan2
- GDF3 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV61713272; called by muse, mutect2, varscan2
- GJB3 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as rs373725070, CM113009; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLUL | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1288022473, COSV59382536; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs749150409; called by mutect2, varscan2
- GNA13 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as COSV71475031; called by muse, mutect2, varscan2
- GNRH1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM094311, COSV52382512; called by muse, mutect2, varscan2
- GOLGA8A | c.1855C>T p.P619S (on ENST00000432566; = p.P591S on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100781653; called by muse, mutect2
- GPC3 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV63668907; called by muse, mutect2, varscan2
- GPR61 | c.881del p.G294Dfs*19 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as COSV63983852; called by mutect2, pindel, varscan2
- GPS1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750722265, COSV57650700; called by mutect2, varscan2
- GREM1 | c.104del p.P35Rfs*49 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV55715863; called by mutect2, pindel, varscan2
- GRIA3 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52073383; called by muse, mutect2, varscan2
- GRIK3 | c.2306C>T p.T769M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs763515718, COSV66143866; called by muse, mutect2, varscan2
- GRM6 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV51447164; called by muse, mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 20/65 reads (31%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GRPEL1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV53827753; called by muse, mutect2, varscan2
- GSTM5 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs867030228, COSV56659285; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56089661; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs782200582; called by muse, mutect2
- GTF2IRD2 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 283/865 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782290129, COSV63100333; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1554532825, COSV57032033; called by muse, mutect2, varscan2
- GUCY2C | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201111235, COSV53790694; called by muse, mutect2, varscan2
- GYPC | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs149400883; called by muse, mutect2, varscan2
- HAUS1 | c.52del p.I18Yfs*12 | Frame Shift Del (DEL) | VAF 50/190 reads (26%) | catalogued as rs751752301; called by mutect2, varscan2
- HCFC1 | c.5189G>A p.S1730N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as COSV60075480; called by muse, varscan2
- HCN4 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56085868; called by muse, mutect2, varscan2
- HDAC5 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs369028803; called by muse, mutect2, varscan2
- HECW1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV67836354; called by muse, mutect2, varscan2
- HECW1 | c.2996G>A p.R999H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs372121389, COSV67838145; called by muse, mutect2, varscan2
- HEPH | c.3106G>A p.A1036T (on ENST00000343002; = p.A769T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as rs1446118910, COSV57968781; called by muse, mutect2, varscan2
- HERC4 | c.2293T>A p.L765I (on ENST00000395198 / NM_022079.3; = p.L757I on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.669); catalogued as COSV53273641; called by muse, mutect2, varscan2
- HGF | c.1736T>G p.L579R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55953857; called by muse, mutect2, varscan2
- HHIPL1 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236101269, COSV100415414; called by muse, mutect2, varscan2
- HIC1 | c.1729C>T p.R577C (on ENST00000322941 / NM_001098202.1; = p.R558C on NM_006497.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53972185; called by muse, mutect2, varscan2
- HIP1R | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53439342, COSV53443455; called by muse, mutect2, varscan2
- HLA-F | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV52576673; called by muse, mutect2, varscan2
- HLA-G | c.617C>G p.A206G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV64406376; called by muse, mutect2, varscan2
- HLA-G | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 25/113 reads (22%) | catalogued as rs752829354; called by mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 6/50 reads (12%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs767148651; called by mutect2, varscan2
- HRG | c.1507T>A p.S503T | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); catalogued as COSV51646957; called by muse, mutect2, varscan2
- HSP90B1 | c.2361_2363del p.D787del | In Frame Del (DEL) | VAF 68/255 reads (27%) | catalogued as rs1272069908; called by mutect2, pindel, varscan2
- HSPG2 | c.2449C>A p.P817T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65974950; called by muse, mutect2, varscan2
- HTR1A | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60499942, COSV60500518; called by muse, mutect2, varscan2
- HTR1F | c.617G>C p.R206T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.077); catalogued as COSV100138012, COSV60390743; called by muse, mutect2, varscan2
- HTT | c.6708_6709del p.H2238Ffs*6 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as COSV61866360; called by mutect2, pindel
- ICE1 | c.6427C>T p.P2143S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56829309; called by muse, mutect2, varscan2
- IFT88 | c.2405G>A p.G802D (on ENST00000319980 / NM_001318493.2; = p.G793D on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV60675617; called by muse, mutect2, varscan2
- IGF2 | c.248G>A p.R83H (on ENST00000434045 / NM_001127598.3; = p.R27H on NM_000612.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1356855570, COSV56098592; called by muse, mutect2, varscan2
- IGSF1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1215064968, COSV63836099; called by muse, varscan2
- IGSF3 | c.1588C>T p.R530C (on ENST00000369486 / NM_001007237.3; = p.R550C on NM_001542.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764711529, COSV59595776; called by muse, mutect2
- IGSF8 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs749690462, COSV58758771; called by muse, mutect2, varscan2
- IL1RL1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as rs772536038, COSV52112814; called by muse, mutect2, varscan2
- IL4R | c.1306T>C p.S436P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99405404; called by muse, mutect2
- ILDR1 | c.1477C>T p.R493W (on ENST00000344209 / NM_001199799.2; = p.R449W on NM_175924.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs556882881, COSV56552149; called by muse, mutect2, varscan2
- ILRUN | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs748166159, COSV64990898; called by muse, mutect2, varscan2
- INF2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs755015990, CD1110965, COSV53034983; called by muse, mutect2, varscan2
- INF2 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs766510967, COSV53034993; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPP4B | c.2363T>A p.M788K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV53725091, COSV53737421; called by muse, mutect2, varscan2
- INPP5K | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457203628, COSV57440558; called by muse, mutect2, varscan2
- INVS | c.2506A>G p.T836A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV52442899; called by muse, mutect2, varscan2
- IQSEC2 | c.3356C>T p.T1119M (on ENST00000642864 / NM_001111125.3; = p.T914M on NM_015075.2) | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs782558010, COSV64727230; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGAV | c.2487G>A p.W829* | Nonsense Mutation (SNP) | VAF 54/167 reads (32%) | catalogued as rs1208064029, COSV53716567; called by muse, mutect2, varscan2
- ITGB2 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as rs148038936, COSV56611514; called by muse, mutect2, varscan2
- ITIH3 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs1368069746, COSV69649705; called by muse, mutect2, varscan2
- ITLN1 | c.227del p.G76Vfs*92 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV58274815; called by mutect2, pindel, varscan2
- ITPRID1 | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1445115018, COSV60079491; called by muse, mutect2, varscan2
- JADE1 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs867517017, COSV56908212; called by muse, mutect2, varscan2
- JCAD | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs773368532, COSV64758858; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.654); catalogued as rs552936797, COSV58025211; called by muse, mutect2, varscan2
- JMY | c.2843C>A p.T948K | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as COSV101268122; called by muse, mutect2, varscan2
- KAT14 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as rs746718890, COSV66607717; called by muse, mutect2, varscan2
- KATNIP | c.2059T>C p.C687R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.234); catalogued as COSV99852029; called by muse, mutect2, varscan2
- KCNC2 | c.1655T>C p.L552P | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs113015322, COSV54375017; called by muse, mutect2, varscan2
- KCNG1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs1433589748, COSV100857180; called by muse, mutect2, varscan2
- KCNG2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100302111, COSV60269221; called by muse, mutect2, varscan2
- KCNH7 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59806698; called by muse, mutect2, varscan2
- KCNV2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs745621260, COSV66056084; called by muse, mutect2, varscan2
- KDM3A | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs761075398, COSV57223698; called by muse, mutect2, varscan2
- KIAA0232 | c.3988C>T p.R1330C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.707); catalogued as rs951493414, COSV56927270; called by muse, mutect2, varscan2
- KIAA1549L | c.2206T>C p.S736P (on ENST00000321505; = p.S1033P on NM_012194.3) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55778252; called by muse, mutect2, varscan2
- KIF1C | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771628064, COSV57905934; called by muse, mutect2, varscan2
- KIF21A | c.3703del p.I1235Ffs*7 (on ENST00000361418 / NM_001378440.1; = p.I1222Ffs*7 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | catalogued as rs761074592; called by mutect2, varscan2
- KIRREL1 | c.1903G>A p.G635S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as rs770599820, COSV63289914; called by muse, mutect2, varscan2
- KIT | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55413124; called by muse, mutect2, varscan2
- KLF15 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1400391304, COSV99955375; called by muse, mutect2, varscan2
- KLF4 | c.1286A>T p.D429V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65929349; called by muse, mutect2, varscan2
- KLF4 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV65929351; called by muse, mutect2, varscan2
- KLHDC9 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs373571786; called by muse, mutect2, varscan2
- KMT2A | c.11456G>A p.R3819H | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1330841358, COSV63286232; called by muse, mutect2, varscan2
- KNOP1 | c.467del p.K156Rfs*57 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs960845807, COSV54929560; called by mutect2, pindel, varscan2
- KRT15 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54181020; called by muse, mutect2, varscan2
- KRT37 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs140701476, COSV56659104; called by muse, mutect2, varscan2
- LAMA5 | c.11046G>T p.E3682D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV53366856; called by muse, mutect2, varscan2
- LAMA5 | c.8641T>C p.Y2881H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53366871; called by muse, mutect2, varscan2
- LAMP1 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV100208780; called by muse, mutect2, varscan2
- LARP4B | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60222752; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV65473126, COSV65473260; called by pindel, varscan2
- LENG8 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58727057; called by muse, mutect2, varscan2
- LETM1 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57103079; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LHX9 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV61326779; called by muse, mutect2, varscan2
- LIG1 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV54394241; called by muse, mutect2, varscan2
- LMAN2 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs775457049, COSV57423916, COSV57425200; called by muse, mutect2, varscan2
- LMNB1 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as COSV54399144; called by muse, mutect2, varscan2
- LMO7 | c.3979C>T p.L1327F (on ENST00000357063; = p.L1008F on NM_005358.5) | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV58543244; called by muse, mutect2, varscan2
- LOXL4 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99584226; called by muse, mutect2, varscan2
- LPCAT2 | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs781024961, COSV50897739; called by muse, mutect2, varscan2
- LRFN2 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775092097, COSV57831722; called by muse, mutect2, varscan2
- LRP10 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs201213246, COSV62078133; called by muse, mutect2, varscan2
- LRP12 | c.2434G>T p.A812S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV52632195; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs1557715031, COSV58440688; called by mutect2, pindel, varscan2
- LRRTM2 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs1377007255, COSV51223701; called by muse, mutect2, varscan2
- LRRTM4 | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV69141173; called by muse, mutect2, varscan2
- LSM14A | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.458); catalogued as rs377088182; called by muse, mutect2, varscan2
- LY9 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs199601456, COSV54433623; called by muse, mutect2, varscan2
- LYAR | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs757496286, COSV58643553; called by muse, mutect2, varscan2
- MAD2L2 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52418096; called by muse, mutect2, varscan2
- MADD | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV60627875; called by muse, mutect2, varscan2
- MAN2B2 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1287834954, COSV53455521; called by muse, mutect2, varscan2
- MAN2C1 | c.1716_1718del p.L573del | In Frame Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs766963781; called by pindel, varscan2
- MAP1LC3B2 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV61010466; called by muse, mutect2, varscan2
- MAP1S | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs757253194, COSV60723722; called by muse, mutect2, varscan2
- MAP2 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758141796, COSV52301445; called by muse, mutect2, varscan2
- MAP7D1 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60217623; called by muse, varscan2
- MAST2 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs772807759, COSV63618267; called by muse, mutect2, varscan2
- MCF2 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100644791; called by muse, mutect2
- MCM2 | c.1588T>C p.S530P | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413473; called by muse, mutect2, varscan2
- MDC1 | c.549dup p.S184Ifs*14 | Frame Shift Ins (INS) | VAF 24/80 reads (30%) | catalogued as rs1185288475; called by mutect2, varscan2
- MDN1 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as COSV65526632; called by muse, mutect2, varscan2
- METTL7B | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV57698646; called by muse, mutect2, varscan2
- MFGE8 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs375727875; called by muse, mutect2, varscan2
- MFNG | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199609888, COSV63690657; called by muse, mutect2, varscan2
- MFRP | c.314C>T p.T105I (on ENST00000449574; = p.T481I on NM_031433.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.887); catalogued as COSV60991108; called by muse, mutect2, varscan2
- MGRN1 | c.1295C>A p.A432D | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV52152959; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs765803753; called by mutect2, pindel, varscan2
- MLH3 | c.4276G>A p.A1426T (on ENST00000355774 / NM_001040108.2; = p.A1402T on NM_014381.3) | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs753388082, COSV53157381; called by muse, mutect2, varscan2
- MMEL1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1370095502, COSV56524277; called by muse, mutect2, varscan2
- MMP17 | c.661del p.D221Tfs*36 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV100861833; called by mutect2, varscan2
- MON2 | c.3509A>G p.Q1170R | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54811895; called by muse, mutect2, varscan2
- MPIG6B | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV65389532; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs757691558; called by mutect2, varscan2
- MROH5 | c.92del p.P31Lfs*6 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as rs748849454; called by mutect2, pindel, varscan2
- MRTFA | c.3013del p.L1005Sfs*62 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV99960746; called by mutect2, varscan2
- MSH3 | c.3339G>A p.M1113I | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145769847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSLNL | c.1827del p.S610Afs*80 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as rs763258321; called by mutect2, pindel, varscan2
- MST1R | c.2649+1G>A p.X883_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as COSV56571897; called by muse, mutect2, varscan2
- MTNR1B | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs182349376, CM121587, COSV57067834; ClinVar: risk factor; called by muse, varscan2
- MTNR1B | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); catalogued as rs370131617; called by muse, varscan2
- MTX2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 229/805 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV50888846; called by muse, mutect2, varscan2
- MUC4 | c.12852del p.T4285Qfs*142 (on ENST00000463781 / NM_018406.7; = p.T49Qfs*142 on NM_004532.6) | Frame Shift Del (DEL) | VAF 74/310 reads (24%) | catalogued as rs747797305; called by mutect2, varscan2
- MXD3 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57463839; called by muse, mutect2, varscan2
- MXRA5 | c.6421C>T p.R2141C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs772595689, COSV54243783; called by muse, mutect2, varscan2
- MYBBP1A | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs181039881; called by muse, mutect2
- MYBPC2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs372880371; called by muse, mutect2, varscan2
- MYCBP2 | c.2999C>T p.A1000V (on ENST00000357337; = p.A1038V on NM_015057.5) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV62031541; called by muse, mutect2, varscan2
- MYEF2 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 45/151 reads (30%) | catalogued as COSV51045901; called by muse, mutect2, varscan2
- MYH14 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1270544217, COSV51819425, COSV99222586; called by muse, mutect2, varscan2
- MYH8 | c.5155C>A p.L1719I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs766719917, COSV101238802; called by mutect2, varscan2
- MYH9 | c.4975G>A p.A1659T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as rs371410108; called by muse, mutect2, varscan2
- MYH9 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV53390806; called by muse, mutect2, varscan2
- MYO1F | c.141+1G>A p.X47_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as rs201353639, COSV57798281; called by muse, mutect2, varscan2
- MYO1G | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV51856132; called by muse, mutect2, varscan2
- MYO3B | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs376278701; called by muse, mutect2, varscan2
- MYOD1 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs781508900, COSV51454888; called by muse, mutect2, varscan2
- MYOF | c.2167C>T p.R723* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as rs780482700, COSV63702355; called by muse, mutect2, varscan2
- MYOZ2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as rs374655743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766816369, COSV60510491; called by muse, mutect2, varscan2
- MZF1 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.397); catalogued as rs908489063, COSV53042641; called by muse, mutect2
- NAGPA | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | PolyPhen probably damaging (1); catalogued as COSV56570497; called by muse, varscan2
- NAT8L | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs756660901, COSV100527089; called by muse, mutect2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs763376147; called by mutect2, varscan2
- NCCRP1 | c.620del p.T207Rfs*58 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as COSV59212772; called by pindel, varscan2
- NCKAP1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs774173976, COSV62940734, COSV62942508; called by muse, mutect2, varscan2
- NCKAP5 | c.5423T>C p.L1808P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58462895; called by muse, mutect2, varscan2
- NCOR1 | c.6678G>T p.M2226I | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51987458; called by muse, mutect2, varscan2
- NDUFA4L2 | c.112T>A p.L38M | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61074810; called by muse, mutect2, varscan2
- NEDD4L | c.1198C>T p.R400C (on ENST00000400345 / NM_001144967.3; = p.R380C on NM_015277.6) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460158008, COSV56842835; called by muse, mutect2, varscan2
- NEK5 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as rs1464336533, COSV62881196; called by muse, mutect2, varscan2
- NEO1 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56075840; called by muse, mutect2, varscan2
- NEU2 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52093556; called by muse, mutect2
- NFATC2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.145); catalogued as COSV65359088; called by muse, mutect2, varscan2
- NIPSNAP3A | c.61-2A>C p.X21_splice | Splice Site (SNP) | VAF 33/113 reads (29%) | catalogued as COSV66113562; called by muse, mutect2, varscan2
- NIPSNAP3B | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs565850921, COSV66106388; called by muse, mutect2, varscan2
- NLGN1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV64330145; called by muse, mutect2
- NLGN1 | c.1452C>G p.Y484* | Nonsense Mutation (SNP) | VAF 63/169 reads (37%) | catalogued as COSV64341876; called by muse, mutect2, varscan2
- NLRX1 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as rs1043304177, COSV52707378; called by muse, mutect2, varscan2
- NOD2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs104895486, COSV56053414; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NOL4L | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.498); catalogued as COSV100675698; called by muse, mutect2, varscan2
- NOP2 | c.1511C>T p.A504V (on ENST00000322166 / NM_001258308.2; = p.A500V on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1432601807, COSV59113835; called by muse, mutect2
- NOS3 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368296624; called by muse, mutect2, varscan2
- NPR2 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1563988222, COSV61313380; called by muse, mutect2, varscan2
- NR2C2AP | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV57394344; called by muse, mutect2, varscan2
- NRP1 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs564902260, COSV55173211; called by muse, mutect2, varscan2
- NSUN2 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747293316, COSV52953127; called by muse, mutect2, varscan2
- NSUN2 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99243467; called by muse, mutect2
- NSUN3 | c.617A>G p.D206G | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58936907; called by muse, mutect2, varscan2
- NUDCD3 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs969997957, COSV100622042, COSV58126654; called by muse, mutect2, varscan2
- NUP188 | c.5233C>T p.R1745W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs368625999; called by muse, mutect2, varscan2
- NVL | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as rs749185581, COSV55874700; called by muse, mutect2, varscan2
- NYNRIN | c.2215T>C p.F739L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV66843924; called by muse, mutect2, varscan2
- OBSCN | c.20981del p.P6994Lfs*78 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as rs1558423016; called by mutect2, pindel
- OR10A2 | c.494_496del p.F165del | In Frame Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs757933096; called by pindel, varscan2
- OR1E2 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50265942; called by muse, mutect2, varscan2
- OR52B2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV73209508; called by muse, mutect2
- OR6K2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62743478, COSV62743959; called by muse, mutect2, varscan2
- OR6K3 | c.386T>C p.I129T (on ENST00000368146; = p.I113T on NM_001005327.2) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV104426738, COSV63746142; called by muse, mutect2, varscan2
- OR6K6 | c.367G>A p.A123T (on ENST00000368144; = p.A99T on NM_001005184.1) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs555413873, COSV63743737, COSV63744605; called by muse, mutect2, varscan2
- OR6Y1 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.821); catalogued as COSV56930555; called by muse, mutect2, varscan2
- ORAI3 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs868345841, COSV57944500; called by muse, mutect2, varscan2
- OSBPL1A | c.1854G>A p.W618* (on ENST00000319481 / NM_080597.4; = p.W105* on NM_018030.4) | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV60201277; called by muse, mutect2, varscan2
- OTUD6A | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57974035; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs763394045; called by mutect2, varscan2
- PALD1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs1195060891, COSV54971200; called by muse, mutect2, varscan2
- PAN3 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); catalogued as COSV66710245; called by muse, mutect2
- PAN3 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs769776435, COSV56701109; called by muse, mutect2, varscan2
- PAX3 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); catalogued as rs528350431, COSV60586871, COSV60590754; called by muse, mutect2, varscan2
- PCDH11X | c.2788C>A p.P930T | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100015357; called by muse, mutect2, varscan2
- PCDH18 | c.2245del p.R749Gfs*17 | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | catalogued as rs34760653; called by mutect2, pindel, varscan2
- PCDH7 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62341536; called by muse, mutect2, varscan2
- PCDHA11 | c.1769T>G p.V590G | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56530243; called by muse, mutect2, varscan2
- PCDHA12 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as COSV56509785; called by muse, mutect2, varscan2
- PCDHA12 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); catalogued as COSV56530265; called by muse, mutect2, varscan2
- PCDHA2 | c.2295del p.K766Rfs*29 | Frame Shift Del (DEL) | VAF 69/234 reads (29%) | catalogued as rs558931090, COSV65368078; called by mutect2, pindel, varscan2
- PCDHB11 | c.1409T>C p.I470T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100697180; called by muse, mutect2, varscan2
- PCDHB5 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs61745762, COSV50660611; called by muse, varscan2
- PCDHB5 | c.1655A>G p.D552G | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1554276110, COSV99169579; called by muse, varscan2
- PCDHB6 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV50706785; called by muse, mutect2, varscan2
- PCDHGA6 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.379); catalogued as COSV53997691, COSV54001422; called by muse, mutect2, varscan2
- PCLO | c.15151G>A p.V5051M | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61653484; called by muse, mutect2, varscan2
- PDE1C | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV58522401; called by muse, mutect2, varscan2
- PDZD2 | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771893787, COSV56854330; called by muse, mutect2, varscan2
- PEX13 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV54370979; called by muse, mutect2, varscan2
- PGAP6 | c.1902+1G>A p.X634_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as rs1334844510, COSV99170801; called by muse, mutect2, varscan2
- PGR | c.2157T>A p.N719K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54807190; called by muse, mutect2
- PGRMC2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759473544, COSV56481033; called by muse, mutect2, varscan2
- PHF7 | c.1003T>A p.L335M | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.641); catalogued as COSV59981260; called by muse, mutect2, varscan2
- PHRF1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV52759831; called by muse, mutect2, varscan2
- PIANP | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as rs1168762197, COSV57708334; called by muse, mutect2, varscan2
- PICALM | c.533T>A p.L178H | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62669151, COSV62672385; called by muse, mutect2, varscan2
- PIKFYVE | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1248638890, COSV52246081; called by muse, mutect2, varscan2
- PITPNM1 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as rs560518491, COSV62707717; called by muse, mutect2, varscan2
- PJA1 | c.767T>A p.V256D | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV64053584; called by muse, mutect2, varscan2
- PLAT | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99535426; called by muse, mutect2, varscan2
- PLCB1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs746490695, COSV62058490; called by muse, mutect2, varscan2
- PLEC | c.11189C>T p.S3730L (on ENST00000322810 / NM_201380.4; = p.S3620L on NM_000445.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs782707803, COSV59670556; called by muse, mutect2
- PLEKHA6 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs1440790251, COSV55333361, COSV55341784; called by muse, mutect2, varscan2
- PLEKHA7 | c.3222G>T p.E1074D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV60580804; called by muse, mutect2, varscan2
- PLXNB1 | c.6020C>T p.A2007V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755289308, COSV56492390; called by muse, mutect2, varscan2
- PODNL1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.017); catalogued as rs776936134, COSV54309376; called by muse, mutect2, varscan2
- POLE2 | c.1268T>C p.M423T | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs1289598306, COSV53561189; called by muse, mutect2, varscan2
- POLQ | c.2363G>A p.G788D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51757752; called by muse, mutect2, varscan2
- POLR2E | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53124855; called by muse, mutect2, varscan2
- POLR3B | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs758303166, COSV57277790; called by muse, mutect2, varscan2
- POLR3E | c.2071-1G>T p.X691_splice | Splice Site (SNP) | VAF 44/144 reads (31%) | catalogued as COSV55402182; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PPP1R3C | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53288965; called by muse, mutect2, varscan2
- PPP2R2B | c.1190del p.G397Afs*31 (on ENST00000394409; = p.G463Afs*31 on NM_181674.2) | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | catalogued as rs767808084; called by mutect2, pindel, varscan2
- PPP2R2C | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.117); catalogued as rs1453968502, COSV59446258; called by muse, mutect2, varscan2
- PRAG1 | c.4109C>T p.A1370V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58164639; called by muse, mutect2, varscan2
- PRAMEF14 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1356754467; called by muse, mutect2, varscan2
- PRAMEF7 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as rs1410587983, COSV100435171; called by muse, mutect2, varscan2
- PRAMEF8 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.642); catalogued as rs1355916188; called by mutect2, varscan2
- PRG4 | c.1873A>G p.T625A | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112101975; called by muse, mutect2
- PRKDC | c.4775T>C p.M1592T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV58059399; called by muse, mutect2
- PRKN | c.986dup p.V330Rfs*17 | Frame Shift Ins (INS) | VAF 31/115 reads (27%) | catalogued as rs745647746; called by mutect2, pindel, varscan2
- PRMT7 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV54714320; called by muse, mutect2, varscan2
- PRPF38A | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs752593492, COSV57122927; called by muse, mutect2, varscan2
- PRPF8 | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1242961736, COSV100517137; called by muse, mutect2
- PRR5 | c.514C>T p.R172C (on ENST00000336985 / NM_181333.4; = p.R163C on NM_015366.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs760293496, COSV50059998, COSV99134819; called by muse, mutect2
- PRUNE2 | c.8384A>G p.D2795G | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56318325; called by muse, mutect2, varscan2
- PSD2 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV51205596; called by muse, mutect2, varscan2
- PSG6 | c.1223T>C p.M408T | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.124); catalogued as rs749933600, COSV51835768; called by muse, mutect2, varscan2
- PSMC4 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50096810; called by muse, mutect2, varscan2
- PTCHD3 | c.1764del p.F588Lfs*18 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | catalogued as rs1448522271; called by mutect2, pindel, varscan2
- PTGFRN | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV67799189; called by muse, mutect2, varscan2
- PTPN18 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV51560049; called by muse, mutect2, varscan2
- PTPRD | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61932719; called by muse, mutect2, varscan2
- PTPRN | c.356del p.P119Qfs*81 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs759562798; called by mutect2, varscan2
- PTPRS | c.3382G>A p.V1128I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs371881792; called by muse, mutect2, varscan2
- PUS3 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs201659793, COSV57101887; called by muse, mutect2, varscan2
- PUS3 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755231389, COSV57104018; called by muse, mutect2, varscan2
- QRICH2 | c.3202C>A p.L1068M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53155939; called by muse, mutect2, varscan2
- RAB28 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746466147, COSV56541417; called by muse, mutect2, varscan2
- RAB40C | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV50194557; called by muse, varscan2
- RAB40C | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs746975761, COSV50193823; called by muse, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAC1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100641080; called by muse, mutect2, varscan2
- RAC3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.192); catalogued as COSV60710499; called by muse, mutect2, varscan2
- RANBP1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); catalogued as rs771917916, COSV59334180, COSV59335692; called by muse, mutect2, varscan2
- RANBP6 | c.1364T>C p.L455S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52390759; called by muse, mutect2, varscan2
- RAPGEF5 | c.1171C>T p.Q391* (on ENST00000401957 / NM_001367602.2; = p.Q694* on NM_012294.5) | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV59788541; called by muse, mutect2, varscan2
- RAVER1 | c.1795G>A p.A599T (on ENST00000615032; = p.G725D on NM_133452.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV53347368; called by muse, mutect2, varscan2
- RBM27 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54592525; called by muse, mutect2, varscan2
- RECQL4 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761231404, COSV56742339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REXO1 | c.1312T>C p.S438P | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs780025948, COSV50084750; called by muse, mutect2, varscan2
- RFLNB | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs782472948, COSV61239297; called by muse, mutect2, varscan2
- RHBDD2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV50087923; called by muse, mutect2, varscan2
- RHOA | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV69041801, COSV69042207; called by muse, mutect2
- RIF1 | c.1414del p.S472Pfs*34 | Frame Shift Del (DEL) | VAF 72/256 reads (28%) | catalogued as COSV54616696; called by mutect2, varscan2
- RIMS2 | c.710C>T p.P237L (on ENST00000666250 / NM_001348490.2; = p.P45L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99199880; called by muse, mutect2, varscan2
- RLF | c.4255del p.Y1419Ifs*6 | Frame Shift Del (DEL) | VAF 50/188 reads (27%) | catalogued as COSV65652466; called by mutect2, pindel, varscan2
- RNASEK-C17orf49 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52351079; called by muse, mutect2, varscan2
- RNF122 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56359789; called by muse, mutect2, varscan2
- RNF213 | c.8353G>A p.A2785T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758896947, COSV60399100; called by muse, mutect2, varscan2
- RNF31 | c.2590C>T p.L864F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60727812; called by muse, mutect2, varscan2
- ROBO2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59927979; called by muse, mutect2, varscan2
- ROS1 | c.3428T>C p.V1143A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63859153; called by muse, varscan2
- RPL23 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV55560238; called by muse, mutect2, varscan2
- RPS27 | c.43_45del p.E15del | In Frame Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs770671657; called by pindel, varscan2
- RPTOR | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201551267; called by muse, mutect2, varscan2
- RPUSD1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383444631, COSV50101643, COSV50103021; called by muse, mutect2, varscan2
- RTL5 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV65452753; called by muse, mutect2, varscan2
- RUFY3 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.2); catalogued as COSV99887952; called by muse, mutect2
- RXFP1 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV57053955; called by muse, mutect2, varscan2
- RXRA | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1220410660, COSV62684014, COSV62684022; called by muse, mutect2, varscan2
- RYR3 | c.3035A>G p.K1012R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.909); catalogued as COSV66802290; called by muse, mutect2, varscan2
- S1PR1 | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100541683; called by muse, mutect2
- SASH1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369655037; called by muse, mutect2, varscan2
- SC5D | c.36T>G p.F12L | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV50612764; called by muse, mutect2, varscan2
- SC5D | c.461A>G p.H154R | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50613426; called by muse, mutect2, varscan2
- SCAF11 | c.1036T>A p.C346S | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as COSV65478123; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 84/181 reads (46%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SCN4A | c.5451G>T p.W1817C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.078); catalogued as COSV71128050; called by muse, mutect2, varscan2
- SCN5A | c.3583C>T p.R1195C (on ENST00000333535 / NM_198056.3; = p.R1194C on NM_000335.5) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs864622440, COSV61115870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16B | c.1299dup p.S434Qfs*14 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs768388757; called by mutect2, varscan2
- SEC23B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs190721221; called by muse, mutect2, varscan2
- SEMA3F | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50033053; called by muse, mutect2, varscan2
- SETBP1 | c.3770A>G p.D1257G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs777741294, COSV99955017; called by muse, mutect2, varscan2
- SETDB1 | c.2767C>T p.R923W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54982099; called by muse, mutect2, varscan2
- SFSWAP | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV55524198; called by muse, mutect2, varscan2
- SH2B3 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1372022451; called by muse, mutect2
- SH3PXD2A | c.2907G>T p.R969S (on ENST00000369774 / NM_001365079.1; = p.R941S on NM_014631.2) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV60119031; called by muse, mutect2, varscan2
- SH3PXD2B | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1470883147, COSV61128650; called by muse, mutect2
- SIGIRR | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV58989002; called by muse, mutect2, varscan2
- SIGLEC1 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV52468957; called by muse, mutect2, varscan2
- SIM2 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV51771326; called by muse, mutect2, varscan2
- SIPA1L3 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs779170658, COSV55911991; called by muse, mutect2, varscan2
- SIRPA | c.400T>C p.F134L | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100605417; called by muse, mutect2
- SIRPG | c.447del p.V150Wfs*15 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as COSV53808421; called by mutect2, pindel, varscan2
- SKIL | c.1589T>C p.I530T | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV52061538; called by muse, mutect2
- SLC12A5 | c.3029C>T p.P1010L (on ENST00000454036 / NM_001134771.2; = p.P987L on NM_020708.5) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs755363281, COSV51644556; called by muse, mutect2, varscan2
- SLC13A3 | c.1392del p.A465Pfs*38 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs780410569; called by mutect2, pindel, varscan2
- SLC15A3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as rs1254599679, COSV50014725; called by muse, mutect2, varscan2
- SLC18A1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs779846411, COSV52350145; called by muse, mutect2, varscan2
- SLC1A7 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs755953710, COSV65198886; called by muse, mutect2, varscan2
- SLC25A10 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1377569042, COSV58971307; called by muse, mutect2, varscan2
- SLC25A53 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.266); catalogued as rs782093486, COSV62460091; called by muse, mutect2, varscan2
- SLC26A1 | c.1730del p.G577Afs*46 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | catalogued as rs756900523; called by pindel, varscan2
- SLC26A1 | c.1632del p.P545Rfs*78 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs1265696919; ClinVar: likely benign; called by pindel, varscan2
- SLC27A2 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373587117, COSV51061109; called by muse, mutect2, varscan2
- SLC2A13 | c.1483T>C p.F495L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99787161; called by muse, mutect2
- SLC35E3 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV60118200; called by muse, mutect2, varscan2
- SLC35F3 | c.230G>A p.C77Y (on ENST00000366617 / NM_001300845.1; = p.C146Y on NM_173508.4) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64020815; called by muse, mutect2, varscan2
- SLC39A12 | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101069843, COSV66201063; called by muse, mutect2, varscan2
- SLC44A3 | c.1722del p.F574Lfs*4 (on ENST00000271227 / NM_001114106.3; = p.F526Lfs*4 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 96/393 reads (24%) | catalogued as rs752543591, COSV54732637; called by mutect2, pindel, varscan2
- SLC4A10 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55780444; called by muse, mutect2, varscan2
- SLC5A10 | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as COSV58760488; called by muse, mutect2, varscan2
- SLC6A1 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV55117458; called by muse, mutect2, varscan2
- SLCO1A2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376154842; called by muse, mutect2, varscan2
- SMARCA5 | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756443687, COSV51645545; called by muse, mutect2, varscan2
- SMPD1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs559088058, CM023145, CM023146, COSV54967175; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- SNAP47 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs200446429, COSV59919281; called by muse, mutect2, varscan2
- SOX17 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV52026932; called by muse, mutect2, varscan2
- SP5 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64623579; called by muse, mutect2, varscan2
- SPAG17 | c.6652C>T p.R2218C | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs201492235, COSV100309251, COSV60464170; called by muse, mutect2, varscan2
- SPEF2 | c.3603T>G p.N1201K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.014); catalogued as COSV61551613; called by muse, mutect2, varscan2
- SPEM1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs375418264; called by muse, mutect2, varscan2
- SPHKAP | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs760142985, COSV100764524, COSV60888996; called by muse, mutect2, varscan2
- SPPL2B | c.1444C>A p.L482M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101476119; called by muse, mutect2, varscan2
- SPRED2 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs754327382, COSV100710333, COSV62694783; called by muse, mutect2, varscan2
- SPRED3 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs760930195, COSV58313484; called by muse, mutect2, varscan2
- SPTB | c.6446C>T p.T2149M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs535592697, COSV61552370; called by muse, mutect2, varscan2
- SRP68 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1211586857, COSV57163952; called by muse, mutect2, varscan2
- SRSF11 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1264485845, COSV63937454; called by muse, mutect2
- ST13 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751496137, COSV53422918; called by muse, mutect2, varscan2
- STARD13 | c.2516C>A p.T839N (on ENST00000336934 / NM_001243476.3; = p.T721N on NM_052851.3) | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as COSV55234587; called by muse, mutect2, varscan2
- STBD1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52954157; called by muse, mutect2, varscan2
- STC2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs373237346; called by muse, mutect2, varscan2
- STK11IP | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779471681, COSV55253251; called by muse, mutect2, varscan2
- STPG2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs779688604, COSV54792040; called by muse, mutect2, varscan2
- STRIP2 | c.1649C>A p.P550H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50806689, COSV50811315; called by muse, mutect2, varscan2
- STXBP5 | c.2420C>T p.T807M (on ENST00000321680 / NM_001127715.2; = p.T771M on NM_139244.4) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs777806209, COSV51655744; called by muse, mutect2, varscan2
- STYXL2 | c.3164del p.P1055Qfs*39 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as COSV54803534; called by mutect2, pindel, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SUZ12 | c.1972C>A p.L658I | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100497104; called by muse, mutect2, varscan2
- SYNDIG1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs772842930, COSV65237829; called by muse, mutect2, varscan2
- TAF15 | c.1589dup p.Y531Lfs*56 (on ENST00000605844 / NM_139215.3; = p.Y528Lfs*56 on NM_003487.4) | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | catalogued as rs770087298; called by mutect2, varscan2
- TAP2 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66500473; called by muse, mutect2, varscan2
- TBC1D9B | c.3148G>A p.A1050T (on ENST00000356834 / NM_198868.3; = p.A1033T on NM_015043.4) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs759500259, COSV62283357; called by muse, mutect2, varscan2
- TBCK | c.952G>A p.A318T (on ENST00000273980 / NM_001163436.4; = p.A255T on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV56759884; called by muse, mutect2, varscan2
- TBL1XR1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61791394, COSV61791932; called by muse, mutect2, varscan2
- TBL3 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1172110224, COSV100225089; called by muse, mutect2
- TBRG4 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51833856; called by muse, mutect2, varscan2
- TBX10 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs150805271; called by mutect2, varscan2
- TBXT | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1186011414, COSV51618026; called by mutect2, varscan2
- TCIRG1 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV55836849; called by muse, mutect2, varscan2
- TCOF1 | c.4391C>T p.A1464V (on ENST00000377797 / NM_001135243.1; = p.A1387V on NM_000356.4) | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1008728630, COSV50533869; called by muse, mutect2, varscan2
- TDGF1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.939); catalogued as rs200480549, COSV56127780; called by mutect2, varscan2
- TDRD5 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867687242, COSV54242060; called by muse, mutect2, varscan2
- TEAD1 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV57568462; called by muse, mutect2
- TECTA | c.4412C>T p.A1471V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV50761112; called by muse, mutect2, varscan2
- TERF1 | c.1186A>G p.R396G (on ENST00000276603 / NM_017489.3; = p.R376G on NM_003218.4) | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV52579090; called by muse, mutect2, varscan2
- TESMIN | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.99); catalogued as COSV54834155; called by muse, mutect2, varscan2
- TET2 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.231); catalogued as COSV54424622; called by mutect2, varscan2
- TEX15 | c.7523C>T p.A2508V (on ENST00000256246; = p.A2891V on NM_001350162.2) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs908404536, COSV56349697; called by muse, mutect2, varscan2
- THOP1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1235555809, COSV57019098, COSV57020028; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as COSV50235787; called by mutect2, varscan2
- TIFAB | c.473del p.P158Lfs*58 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs769374871; called by mutect2, pindel, varscan2
- TIMP4 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs368380293; called by muse, mutect2, varscan2
- TLE3 | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58172654; called by muse, mutect2, varscan2
- TLL1 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs565356664, COSV50266199, COSV50309373; called by muse, mutect2
- TMEM109 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs753654818, COSV50003100; called by muse, mutect2, varscan2
- TMEM132D | c.1667A>T p.E556V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101243102; called by muse, mutect2, varscan2
- TMEM145 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs975167884, COSV52094926; called by muse, mutect2, varscan2
- TMEM222 | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV65027414; called by muse, mutect2, varscan2
- TMOD1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs753776204, COSV52246463; called by muse, mutect2, varscan2
- TMPRSS6 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV60975290, COSV60981956; called by muse, mutect2, varscan2
- TNK2 | c.2491del p.Q831Rfs*2 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | catalogued as COSV100361518; called by mutect2, pindel, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TOP2B | c.102dup p.E35Rfs*10 (on ENST00000264331 / NM_001330700.2; = p.E30Rfs*10 on NM_001068.3) | Frame Shift Ins (INS) | VAF 34/108 reads (31%) | catalogued as rs1185227770; called by mutect2, varscan2
- TOPBP1 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs201984734; called by muse, mutect2, varscan2
- TP63 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53202869, COSV53225364; called by muse, varscan2
- TRDMT1 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58320197; called by muse, mutect2, varscan2
- TRIM3 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV61984928; called by muse, mutect2, varscan2
- TRIM33 | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs371685549; called by muse, mutect2, varscan2
- TRIM68 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs758373806, COSV56169151; called by muse, mutect2, varscan2
- TRMO | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64292400, COSV99056098; called by muse, mutect2, varscan2
- TRO | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV51505137; called by muse, mutect2, varscan2
- TRPC3 | c.2380A>G p.M794V (on ENST00000379645 / NM_001366479.2; = p.M721V on NM_003305.2) | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53378657; called by muse, mutect2, varscan2
- TRPV1 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV51521993; called by muse, mutect2, varscan2
- TRPV6 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs111318322; called by muse, mutect2, varscan2
- TSPAN9 | c.40T>A p.F14I | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV50726264; called by muse, mutect2, varscan2
- TSPYL1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.793); catalogued as rs755262799, COSV63994209; called by muse, mutect2, varscan2
- TSPYL1 | c.52A>T p.I18F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV63994212; called by muse, mutect2, varscan2
- TSPYL5 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV59071180; called by muse, mutect2, varscan2
- TTLL8 | c.2258G>A p.G753D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99838643; called by muse, mutect2, varscan2
- TTN | c.47816A>C p.D15939A (on ENST00000591111; = p.D8515A on NM_003319.4) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | PolyPhen benign (0.111); catalogued as COSV60225029; called by muse, mutect2, varscan2
- TTN | c.43678A>G p.K14560E (on ENST00000591111; = p.K7136E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/85 reads (9%) | PolyPhen benign (0.169); catalogued as COSV100630403; called by muse, mutect2, varscan2
- TUBA4A | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV50280144; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs760251146; called by mutect2, varscan2
- U2AF2 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58272791; called by muse, mutect2, varscan2
- UACA | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs753673926, COSV59854684; called by muse, mutect2, varscan2
- UBA6 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1284679469, COSV59175286, COSV59177903; called by muse, mutect2, varscan2
- UBE3A | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs745363984, COSV51668858; called by muse, mutect2, varscan2
- UBN2 | c.655T>C p.S219P | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99944480; called by muse, mutect2, varscan2
- UBR4 | c.8729G>A p.S2910N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752803245, COSV100921912; called by muse, mutect2, varscan2
- UBR5 | c.3991C>T p.R1331C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs1450677318, COSV55299277; called by muse, mutect2, varscan2
- UHRF1BP1 | c.4016G>A p.G1339D | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.957); catalogued as COSV51958522; called by muse, mutect2, varscan2
- ULK3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs1197270071, COSV99174008; called by muse, mutect2
- UNC5D | c.1671G>A p.M557I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99778831; called by muse, mutect2
- UROC1 | c.1940G>A p.C647Y | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99332409; called by muse, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs764735138; called by mutect2, varscan2
- USP42 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.077); catalogued as COSV60362974; called by muse, mutect2, varscan2
- USP6NL | c.807dup p.Q270Sfs*5 | Frame Shift Ins (INS) | VAF 27/80 reads (34%) | catalogued as rs1566125874; called by mutect2, pindel, varscan2
- USP7 | c.906G>T p.V302= | Splice Region (SNP) | VAF 43/140 reads (31%) | catalogued as COSV61216362; called by muse, mutect2, varscan2
- VEZF1 | c.622A>G p.N208D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.807); catalogued as COSV51969703; called by muse, mutect2, varscan2
- VIRMA | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376403379; called by muse, mutect2, varscan2
- VPS13D | c.3944G>A p.R1315Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV50633775; called by muse, mutect2, varscan2
- VPS39 | c.2452A>G p.N818D (on ENST00000348544 / NM_001301138.2; = p.N807D on NM_015289.5) | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV58791832; called by muse, mutect2, varscan2
- VWA3A | c.1934G>A p.C645Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758290930, COSV100241324; called by mutect2, varscan2
- VWA3B | c.3415C>T p.R1139W | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1450242835, COSV69034217; called by muse, mutect2, varscan2
- WASHC5 | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59199012; called by muse, mutect2, varscan2
- WDR1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1391665071, COSV53332509; called by muse, mutect2, varscan2
- WDR7 | c.3793G>A p.A1265T | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs750574514, COSV54351089; called by muse, mutect2, varscan2
- WIPI2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as rs759604469, COSV56590364; called by muse, mutect2, varscan2
- WNK2 | c.5945G>A p.R1982H (on ENST00000297954 / NM_001282394.1; = p.R1945H on NM_006648.3) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1204473047, COSV52953189; called by muse, mutect2, varscan2
- WNK3 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV63615216; called by muse, mutect2, varscan2
- WNT7B | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs773462729, COSV59751522; called by muse, mutect2, varscan2
- WNT9B | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.547); catalogued as rs202125492, COSV51519442; called by muse, mutect2, varscan2
- WRAP73 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774325847, COSV54562566; called by muse, mutect2, varscan2
- WSCD2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565967983, COSV54587083, COSV54587557; called by muse, mutect2, varscan2
- WWOX | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370737224, COSV68347719; called by muse, mutect2, varscan2
- ZAN | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.329); catalogued as rs183149213; called by mutect2, varscan2
- ZBED8 | c.651A>G p.I217M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs748101427, COSV68824915; called by muse, mutect2, varscan2
- ZBTB21 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252017088, COSV60403893; called by muse, mutect2, varscan2
- ZC3H12C | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs768457807, COSV53710892; called by muse, mutect2, varscan2
- ZC3H18 | c.942del p.A315Qfs*18 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV56322579; called by mutect2, pindel
- ZCCHC13 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV59866524; called by muse, mutect2, varscan2
- ZCCHC7 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1437760895, COSV60959832; called by muse, mutect2, varscan2
- ZDBF2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs866727544, COSV65628505; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs781677398, COSV57709922; called by pindel, varscan2
- ZFAT | c.3678G>T p.E1226D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV64742949; called by muse, mutect2, varscan2
- ZFAT | c.2996G>A p.C999Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245309958, COSV64742952; called by muse, mutect2, varscan2
- ZFHX3 | c.8584G>T p.A2862S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.024); catalogued as COSV51728570; called by muse, mutect2, varscan2
- ZFHX4 | c.6310G>A p.A2104T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs748293539, COSV51479738; called by muse, mutect2, varscan2
- ZNF169 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762656741, COSV61764168; called by muse, mutect2, varscan2
- ZNF317 | c.1075del p.E359Rfs*51 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as COSV56109326; called by mutect2, pindel, varscan2
- ZNF382 | c.1382A>G p.E461G | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV99497733; called by muse, mutect2, varscan2
- ZNF513 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52009325; called by muse, mutect2, varscan2
452 further variants in this file (154 protein-altering or splice-affecting, 270 silent, 28 other) are not listed here.
